Gene-level copy-number profile of tumor specimen ALCH-B1ON-TTP1-A from ALCHEMIST case ALCH-B1ON, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.2 years (26,728 days).
Specimen ALCH-B1ON-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 05c78a24-928c-4a8e-8b1b-4ea52a80de9f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1ON-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/bbb6bd48-a0ce-431c-9d3b-e12060afe219

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 22,066; copy number 2: 34,009; copy number 3: 1,144; copy number 4: 1,234; copy number 5: 289; copy number 6: 13; copy number 7: 42; copy number 9: 2; copy number 11: 2; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,191,915–36,192,170, 1 gene: RN7SL131P.
- chr1:248,590,487–248,601,869, 3 genes: OR2T10, Y_RNA, AC098483.2.
- chr5:132,747,426–132,807,241, 2 genes: CCNI2, SEPTIN8.
- chr7:561,958–565,619, 1 gene (within-gene range 0–2): PRKAR1B-AS2.
- chr7:23,490,473–23,491,893, 2 genes: RPS2P32, Y_RNA.
- chr7:43,940,895–44,019,175, 6 genes (within-gene range 0–2): POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1.
- chr7:44,013,562–44,019,170, 1 gene (within-gene range 0–2): POLR2J4.
- chr7:77,071,751–77,072,237, 1 gene (within-gene range 0–2): AC007000.2.
- chr11:64,803,510–64,811,294, 1 gene: MEN1.
- chr11:64,851,642–64,893,449, 5 genes: EHD1, AP001187.1, MIR194-2HG, MIR192, MIR194-2.
- chr11:117,668,483–117,668,858, 1 gene (within-gene range 0–1): AP001554.1.
- chr12:98,613,405–98,645,113, 1 gene: IKBIP.
- chr12:109,734,166–109,773,508, 1 gene (within-gene range 0–1): FAM222A-AS1.
- chr14:101,026,020–101,046,538, 17 genes (within-gene range 0–1): MIR758, MIR329-1, MIR329-2, MIR494, MIR1193, MIR543, MIR495, MIR376C, MIR376A2, MIR654, MIR376B, MIR376A1, MIR300, MIR1185-1, MIR1185-2, MIR381, MIR487B.
- chr14:105,647,924–105,649,057, 1 gene: COPDA1.
- chr15:25,169,337–25,225,284, 31 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr15:101,562,536–101,562,974, 1 gene: SNRPCP18.
- chr16:589,357–629,272, 1 gene (within-gene range 0–2): RAB40C.
- chr16:14,301,389–14,418,908, 5 genes: MIR193BHG, MIR193B, MIR365A, LINC02130, AC040173.1.
- chr22:43,038,585–43,089,419, 2 genes: TTLL1-AS1, TTLL1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 347 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene, copy number 11: AC239798.1.
- chr1:148,482,548–148,796,325, 8 genes, copy number 6–9: PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1.
- chr1:248,436,359–248,444,316, 1 gene, copy number 6: OR2T7.
- chr3:181,699,608–181,699,883, 1 gene, copy number 5 (within-gene range 4–5): AC117415.1.
- chr3:181,847,526–190,122,437, 177 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:195,274,745–195,443,044, 1 gene, copy number 6 (within-gene range 4–6): ACAP2.
- chr3:195,349,664–198,123,232, 110 genes, copy number 5–6 (broad region; genes not listed).
- chr8:144,330,565–144,336,482, 1 gene, copy number 16: SCRT1.
- chr14:105,583,731–105,601,728, 2 genes, copy number 5–11 (within-gene range 2–11): IGHA2, IGHE.
- chr15:30,516,079–30,600,647, 7 genes, copy number 7: AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8.
- chr17:2,303,383–3,037,741, 30 genes, copy number 7 (within-gene range 1–7): SRR, HNRNPA1P16, TSR1, SNORD91B, SNORD91A, SGSM2, AC006435.3, AC006435.2, MNT, AC006435.1, METTL16, AC006435.4, AC006435.5, RN7SL33P, EIF4A1P9, PAFAH1B1, SAMD11P1, AC015799.1, RN7SL608P, AC005696.2, AC005696.3, CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr19:1,103,926–1,174,268, 2 genes, copy number 5: GPX4, SBNO2.
- chr19:1,259,384–1,279,244, 3 genes, copy number 7: CIRBP, CIRBP-AS1, FAM174C.
- chr19:40,592,883–40,629,818, 1 gene, copy number 6: LTBP4.
- chr19:41,883,173–41,930,150, 2 genes, copy number 6: ARHGEF1, ERFL.

Autosomal genes at a single copy (total copy number 1): 19,276. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
